CCDI case PBCCDC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/e397fa05-a874-4453-a408-1ea9cae747e8

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 4.5 years (1,652 days).

Biospecimens (3 samples)
- Sample 0DOBSR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOBT5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOBTC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
